Somatic mutation profile of tumor specimen BA2936D (aliquot aq-BA2936D) from BEATAML1.0 case 2027, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.6 years (26,527 days).
Specimen BA2936D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29f8fe46-3c77-4209-80f4-ef554ffafe1a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2416D (Solid Tissue Normal), aliquot aq-BA2416D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d05acd33-ddc3-4c87-b90e-62b45136cd7a

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 1, In Frame Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 34/187 reads (18%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CIAO1 | c.147C>A p.S49R | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.071); catalogued as COSV99302614; called by muse, mutect2
- DOCK4 | c.5713G>A p.V1905I | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.041); catalogued as rs754293240, COSV101447831; called by muse, varscan2
- GRK2 | c.736G>A p.V246I | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.611); catalogued as rs770458416, COSV100419812; called by muse, mutect2, varscan2
- ADIPOQ | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 48/272 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- CAVIN3 | c.587G>T p.R196L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EVL | c.410A>C p.Q137P (on ENST00000402714 / NM_001330221.2; = p.Q139P on NM_016337.3) | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- RTBDN | c.284_285insGCA p.R95_A96insH (on ENST00000393233 / NM_001270444.1; = p.R127_A128insH on NM_031429.2) | In Frame Ins (INS) | VAF 14/91 reads (15%) | called by mutect2, pindel, varscan2
- SIGLEC1 | c.4808T>A p.L1603Q | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TNIK | c.3461G>A p.R1154K | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- CNTNAP2 | c.993G>A p.K331= | Silent (SNP) | VAF 74/473 reads (16%) | catalogued as COSV62175290, COSV62182552; called by muse, mutect2, varscan2
- ZNF536 | c.*18G>A | 3'UTR (SNP) | VAF 15/108 reads (14%) | catalogued as rs368007455; called by mutect2, varscan2
